Gene-level copy-number profile of tumor specimen TCGA-AA-3666-01A from TCGA case TCGA-AA-3666, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-AA-3666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.81f5011d-4f2a-4fc4-8597-3bc27701c082.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3666-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6aa6421c-387d-446a-a069-3e9e01869c55

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,181; copy number 2: 28,243; copy number 3: 16,792; copy number 4: 10,204; copy number 5: 891; copy number 6: 70; copy number 7: 1,412; copy number 8: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3666-01A-02D-0903-01): tumor purity 0.82, ploidy 2.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,399 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,770,176–44,830,188, 116 genes, copy number 6–7 (broad region; genes not listed).
- chr6:44,898,711–44,899,295, 1 gene, copy number 6: NUDT19P4.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6–8 (broad region; genes not listed).
- chr18:22,130,603–25,352,190, 68 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:35,002,404–64,313,132, 743 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr21:28,048,404–28,228,667, 2 genes, copy number 5 (within-gene range 3–5): LINC01697, LINC01695.
- chr21:39,373,763–41,037,362, 23 genes, copy number 5: RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3, AL773573.1.
- chr21:44,350,163–45,297,806, 55 genes, copy number 5 (within-gene range 3–5): TRPM2, TRPM2-AS, AP001065.2, AP001065.1, LRRC3-DT, LRRC3, MTCYBP21, MTND6P21, MTND5P1, AP001065.3, LINC02575, AP001065.4, TSPEAR, TSPEAR-AS1, TSPEAR-AS2, AP001066.1, KRTAP10-1, KRTAP10-2, KRTAP10-3, KRTAP10-4, KRTAP10-5, KRTAP10-6, KRTAP10-7, KRTAP10-8, KRTAP10-9, KRTAP10-10, KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2, IMMTP1, KRTAP12-1, KRTAP12-6P, KRTAP10-12, KRTAP10-13P, UBE2G2, LINC01424, SUMO3, PTTG1IP, ITGB2, ITGB2-AS1, AL844908.2, LINC01547, AL844908.1, FAM207A, AP001505.1, LINC00163, LINC00165, PICSAR, SSR4P1, ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205.

Autosomal genes at a single copy (total copy number 1): 2,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
